Surgical pathology report (de-identified scan), TCGA case TCGA-FF-A7CQ, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site SingHealth, specimen TCGA-FF-A7CQ-01A (Primary Tumor).

Patient Results

Requested By:

Histopathology Report

Biopsy No:

Final

Received Date/Time
Reporting Information

Date/Time :
Histopathologist :
Laboratory :

Final
Final

Consultant-In-Charge
Submitting Physician
Histopathology Report

NOT STATED

Final
Final
Final

DIAGNOSIS

RIGHT CERVICAL LYMPH NODE; EXCISION : DIFFUSE
LARGE B-CELL LYMPHOMA.

GROSS DESCRIPTION

Received in formalin is a specimen labelled with patient's data and designated "lymph node biopsy". It consists of 3 pieces of brownish tissue measuring 1.2 x 1 x 0.4cm, submitted entirely. (A1; no reserve)
A separate piece of tissue received fresh measuring 0.9 x 0.5 x 0.5m is snap-frozen for storage.

MICROSCOPIC DESCRIPTION

Histology shows a fragmented lymph node with architectural effacement by a diffuse, patternless proliferation of lymphomatous large cells with a centroblastic nucleolar disposition, scattered mitoses and foci of plasmacytoid differentiation, peppered by "starry-sky" macrophages. The lymphomatous proliferation is strongly positive for pan-B cell marker CD20 and coexpresses postgerminal centre-associated transcription factor MUM.1, but not CD138, which decorates only small numbers of scattered mature plasma cells. The lymphomatous cells also strongly coexpress the antiapoptosis protein bcl-2, which cannot be accounted for by physiological expression in admixed, CD3-positive, reactive, small T-lymphocytes, albeit focally plentiful, while being negative for germinal centre-associated antigen CD10, which highlights only occasional stromal cells and polymorphs, in keeping with an "activated B-cell" phenotypic profile, thereby excluding Burkitt lymphoma in conjunction with a cell proliferation fraction that falls short of 100% (approximately 70-80%) by Ki-67 immunolabelling, as well as a lymphoblastic neoplasm in conjunction with negativity for terminal deoxynucleotidyl transferase, which highlights only a few, scattered, circulating haematogones. Immunostaining for Cyclin D1 is negative within the lymphoid proliferation, highlighting only physiological expression in scattered histiocytic and activated endothelial nuclei, excluding a transformed mantle cell lymphoma. Only a few overrun or disrupted CD21-immunoreactive follicular dendritic meshworks are discerned, providing no support for an origin from a transformed follicular lymphoma.

Pathologist :

ICD-O-3
Lymphoma, diffuse large B Cell
9680/3
Site Cervical lymph node
C27.0
Jed 8/26/13

Printed from:

End of Report

Page: 1 of 1

Source: NCI Genomic Data Commons file abf71b95-d242-4c4d-83ad-c06dffbe65ca (TCGA-FF-A7CQ.3CCFB076-52BE-4A5D-9E49-65516AA9C349.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).